Gene-level copy-number profile of tumor specimen HCM-BROD-0012-C71-86A from HCMI case HCM-BROD-0012-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,744 days).
Specimen HCM-BROD-0012-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ef577644-a15a-47b4-9615-171900dcbba1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0012-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/f665d48d-ad5e-4191-9c91-4d0e9f9a5c3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6,993; copy number 2: 49,321; copy number 3: 2,076; copy number 4: 2; copy number 5: 3; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,462,819–64,473,826, 3 genes, copy number 6: CR769776.2, CYP4F25P, CR769776.1.
- chr9:112,957,722–113,050,043, 3 genes, copy number 5 (within-gene range 2–5): ZNF883, MUPP, ZNF883.

Autosomal genes at a single copy (total copy number 1): 6,979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
